Somatic mutation profile of tumor specimen MP2PRT-PAVNKF-TMP1-A (aliquot MP2PRT-PAVNKF-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVNKF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,302 days).
Specimen MP2PRT-PAVNKF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99fe704b-1f64-42ea-8dfe-152ed4710017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNKF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNKF-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cfdbf00-879b-401c-9041-2b9e55b03742

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.2978C>T p.T993M | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200290721, CM075997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54044253; called by muse, mutect2, varscan2
- PAQR9 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 181/377 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV61417657, COSV61418619; called by muse, mutect2, varscan2
- RRBP1 | c.2716G>A p.E906K (on ENST00000377813 / NM_001365613.2; = p.E473K on NM_004587.3) | Missense Mutation (SNP) | VAF 115/346 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs772448951, COSV55701993; called by muse, mutect2
- FBN2 | c.8512C>A p.Q2838K | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FMN2 | c.2474C>G p.P825R | Missense Mutation (SNP) | VAF 12/402 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2
- KCNC4 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 122/295 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVA1C | c.150C>T p.T50= | Silent (SNP) | VAF 107/416 reads (26%) | called by muse, mutect2, varscan2
- GRM7 | c.366C>T p.F122= | Silent (SNP) | VAF 16/379 reads (4%) | catalogued as COSV63130235, COSV63156217; called by muse, mutect2
- IL20RA | c.312C>T p.Y104= | Silent (SNP) | VAF 67/317 reads (21%) | catalogued as rs771466183; called by muse, mutect2, varscan2
- KIF5A | c.741C>T p.A247= | Silent (SNP) | VAF 90/204 reads (44%) | catalogued as rs769133499, COSV54056036; called by muse, mutect2, varscan2
- ACOT6 | chr14:73613006 C>T | 5'Flank (SNP) | VAF 289/473 reads (61%) | called by muse, mutect2, varscan2
